Somatic mutation profile of tumor specimen TCGA-FC-A6HD-01A (aliquot TCGA-FC-A6HD-01A-11D-A31L-08) from TCGA case TCGA-FC-A6HD, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 77.2 years (28,197 days).
Specimen TCGA-FC-A6HD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66a257a2-67af-4a9f-8e60-957c2be6bf73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FC-A6HD-10A (Blood Derived Normal), aliquot TCGA-FC-A6HD-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d55f519-03f4-469f-937f-504804428feb

The open-access MAF lists 32 somatic variants for this specimen: 21 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 19, Silent 11, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATG7 | c.1528C>G p.H510D | Missense Mutation (SNP) | VAF 90/190 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61613583; called by muse, mutect2, varscan2
- CACNA1S | c.1405C>T p.R469W | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs751576994, COSV62940922; called by muse, mutect2, varscan2
- CCAR2 | c.245T>C p.V82A | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0.16); catalogued as COSV51515554; called by muse, mutect2, varscan2
- CREBRF | c.757A>T p.S253C | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.785); catalogued as COSV51634126; called by muse, mutect2
- CUTA | c.262G>A p.V88M (on ENST00000488034 / NM_001014840.2; = p.V65M on NM_015921.3) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV53382785; called by muse, mutect2, varscan2
- DCAF4L2 | c.160A>G p.M54V | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV60479781; called by muse, mutect2, varscan2
- ESF1 | c.344A>G p.K115R | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.339); catalogued as COSV52522028; called by muse, mutect2, varscan2
- FH | c.899T>A p.L300H | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.853); catalogued as COSV63818394; called by muse, mutect2, varscan2
- LIFR | c.2057T>G p.I686R | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54692719; called by muse, mutect2, varscan2
- MAD2L1 | c.445T>C p.C149R | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV56637100; called by muse, mutect2, varscan2
- MED13 | c.2506A>G p.T836A | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV67264533; called by muse, mutect2, varscan2
- NOS2 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1443847007, COSV58224861; called by muse, mutect2
- OBSCN | c.20343C>A p.H6781Q | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV62601545; called by muse, mutect2, varscan2
- OTX1 | c.989C>G p.A330G | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV56995173; called by muse, mutect2, varscan2
- RECQL | c.760A>G p.T254A | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200538229, COSV69658850; called by muse, mutect2, varscan2
- SLC2A8 | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs768388435, COSV64894168; called by muse, mutect2, varscan2
- SPRR2E | c.145C>A p.Q49K | Missense Mutation (SNP) | VAF 76/339 reads (22%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV64203835; called by muse, mutect2, varscan2
- SSC4D | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as rs1175356820, COSV51882864; called by muse, mutect2
- TSEN54 | c.949G>T p.A317S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.022); catalogued as rs201125812, COSV51360178; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSPA4 | c.1280_1284del p.P427Lfs*2 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- ZBTB41 | c.2582_2605del p.T861_N868del | In Frame Del (DEL) | VAF 48/228 reads (21%) | called by mutect2, pindel
- C4orf19 | c.288C>T p.C96= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as rs758380758, COSV52649622; called by muse, mutect2, varscan2
- FBN3 | c.3051C>T p.F1017= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs1267151230, COSV54462252; called by muse, mutect2, varscan2
- GPNMB | c.981A>G p.P327= | Silent (SNP) | VAF 47/173 reads (27%) | catalogued as COSV51697024; called by mutect2, varscan2
- JUP | c.2151C>T p.H717= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV60278672; called by muse, mutect2, varscan2
- PCDHB16 | c.927C>T p.F309= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV53359504; called by muse, mutect2, varscan2
- PIGX | c.774A>G p.L258= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as rs144273559, COSV56360177; called by muse, mutect2, varscan2
- PTGDR | c.633C>T p.V211= | Silent (SNP) | VAF 38/94 reads (40%) | catalogued as COSV60094269; called by muse, mutect2, varscan2
- PTGFR | c.609A>C p.L203= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV66115524; called by muse, mutect2, varscan2
- SMAD7 | c.1212C>T p.G404= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs1052572, COSV50990381; called by muse, mutect2, varscan2
- TMEM40 | c.327T>C p.V109= | Silent (SNP) | VAF 57/147 reads (39%) | catalogued as COSV53146863, COSV53148756; called by muse, mutect2, varscan2
- WSB2 | c.756C>G p.A252= | Silent (SNP) | VAF 29/156 reads (19%) | catalogued as COSV57477975; called by muse, mutect2, varscan2
